CCDI case PBCERJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/bdaf664f-7ca3-4399-a101-0e7670dea8f0

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 11.9 years (4,343 days).

Biospecimens (2 samples)
- Sample 0DQUA3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQUA4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
